Somatic mutation profile of tumor specimen TCGA-DB-A75K-01A (aliquot TCGA-DB-A75K-01A-11D-A32B-08) from TCGA case TCGA-DB-A75K, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 55.4 years (20,241 days).
Specimen TCGA-DB-A75K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31a20d5c-a9ee-4ade-ab17-d585b137a2ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A75K-10A (Blood Derived Normal), aliquot TCGA-DB-A75K-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aeb378ff-3975-4ea2-8db2-ff9a619cb1ec

The open-access MAF lists 38 somatic variants for this specimen: 28 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 9, Frame Shift Ins 3, Nonsense Mutation 3, In Frame Del 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/64 reads (44%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NF1 | c.7909C>T p.R2637* (on ENST00000358273 / NM_001042492.3; = p.R2616* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 37/120 reads (31%) | catalogued as rs786201367, CM950853, COSV62195872; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NOTCH1 | c.1070_1072del p.F357del | In Frame Del (DEL) | VAF 7/26 reads (27%) | hotspot (GDC flag); called by mutect2, varscan2
- ARSD | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750371469, COSV99472117; called by muse, mutect2, varscan2
- ARSH | c.581G>A p.W194* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV101139820; called by muse, mutect2, varscan2
- CCR3 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs139319342, COSV100656471; called by muse, mutect2, varscan2
- CDC73 | c.577A>G p.K193E | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV66467976; called by muse, mutect2, varscan2
- CDHR1 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs200880106, CM056677, COSV60565170; called by muse, mutect2, varscan2
- CSTF3 | c.1690G>T p.A564S | Missense Mutation (SNP) | VAF 114/286 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV100123963; called by muse, varscan2
- CYLC1 | c.116A>G p.K39R | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100254538; called by muse, mutect2, varscan2
- EPB41L1 | c.991A>T p.R331W | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99150391; called by muse, mutect2, varscan2
- FANCI | c.2385A>C p.K795N | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.376); catalogued as COSV100167885; called by muse, mutect2, varscan2
- HNRNPA1 | c.868T>G p.Y290D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.5); catalogued as COSV99267590; called by muse, mutect2, varscan2
- MYLK3 | c.1726T>G p.Y576D | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101189110; called by muse, mutect2, varscan2
- PCCA | c.1593_1595del p.L532del | In Frame Del (DEL) | VAF 32/81 reads (40%) | catalogued as rs937519016; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- PTPN23 | c.2156G>A p.R719Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs769919664, COSV99650046, COSV99650518; called by muse, varscan2
- RIF1 | c.2559A>C p.K853N | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.142); catalogued as COSV99690504; called by muse, mutect2, varscan2
- SLITRK4 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.04); catalogued as COSV100567309; called by muse, mutect2, varscan2
- TLR10 | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs200661388; called by muse, mutect2, varscan2
- TNFRSF11B | c.484A>T p.K162* | Nonsense Mutation (SNP) | VAF 65/164 reads (40%) | catalogued as COSV99816605; called by muse, mutect2, varscan2
- TTN | c.72536C>T p.P24179L (on ENST00000591111; = p.P16755L on NM_003319.4) | Missense Mutation (SNP) | VAF 34/86 reads (40%) | PolyPhen probably damaging (0.913); catalogued as COSV100609978, COSV59955321; called by muse, mutect2, varscan2
- VSIG4 | c.742A>G p.T248A | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV101038148; called by muse, mutect2, varscan2
- VSNL1 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs1260171799, COSV54597194; called by muse, mutect2, varscan2
- YIPF6 | c.670T>A p.F224I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV101006233; called by muse, mutect2
- CIC | c.462dup p.I155Hfs*5 | Frame Shift Ins (INS) | VAF 17/38 reads (45%) | called by mutect2, pindel, varscan2
- FUBP1 | c.990_993dup p.C332Pfs*20 | Frame Shift Ins (INS) | VAF 98/151 reads (65%) | called by mutect2, pindel, varscan2
- IGKV1-12 | c.172T>C p.Y58H | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- RFX4 | c.540dup p.F181Ifs*15 (on ENST00000392842 / NM_213594.3; = p.F87Ifs*15 on NM_032491.6) | Frame Shift Ins (INS) | VAF 63/212 reads (30%) | called by mutect2, pindel, varscan2
- AMZ1 | c.907C>T p.L303= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100406356; called by muse, mutect2, varscan2
- BCL9 | c.2772A>G p.P924= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV99324979; called by muse, mutect2, varscan2
- CDC42BPG | c.4080T>C p.N1360= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs1024075886, COSV100712050; called by muse, mutect2, varscan2
- DNASE1L1 | c.750G>A p.T250= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as rs781807608, COSV99185914; called by muse, mutect2, varscan2
- FUCA2 | c.1260A>C p.T420= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV99136035; called by muse, mutect2, varscan2
- NPC1L1 | c.111C>T p.D37= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs143153721; called by muse, mutect2, varscan2
- TAF1 | c.2343G>A p.T781= (on ENST00000373790 / NM_138923.4; = p.T802= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as COSV99335532; called by muse, mutect2, varscan2
- UTP20 | c.3138C>T p.A1046= | Silent (SNP) | VAF 41/123 reads (33%) | catalogued as rs201637301, COSV99881478; called by muse, mutect2, varscan2
- ZIC3 | c.786C>T p.S262= | Silent (SNP) | VAF 45/92 reads (49%) | catalogued as COSV54976552, COSV99799641; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840612 G>A | 5'Flank (SNP) | VAF 15/29 reads (52%) | catalogued as rs768082058, COSV58341425; called by muse, mutect2, varscan2
